Somatic mutation profile of tumor specimen C3N-01338-01 (aliquot CPT0088060010) from CPTAC case C3N-01338, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.2 years (18,322 days).
Specimen C3N-01338-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3f28ac3-2940-4508-97dd-6f8c7a18a1db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01338-31 (Blood Derived Normal), aliquot CPT0088120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5343dd72-b176-4894-a2f5-010d30897d88

The open-access MAF lists 301 somatic variants for this specimen: 191 protein-altering or splice-affecting, 75 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 75, Nonsense Mutation 16, Intron 14, 3'UTR 7, RNA 6, 5'UTR 5, Frame Shift Ins 3, 5'Flank 2, Nonstop Mutation 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.273G>C p.M91I | Missense Mutation (SNP) | VAF 26/328 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV57250290, COSV57259763, COSV57263441; called by muse, mutect2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 333/619 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.2984C>T p.A995V | Missense Mutation (SNP) | VAF 78/307 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.833); catalogued as rs868669576, COSV55589511; called by muse, mutect2, varscan2
- ACAN | c.2790C>G p.S930R | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV61358815; called by muse, mutect2
- ACHE | c.1837G>C p.D613H | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as rs1220415220, COSV53822964; called by muse, mutect2
- ADAM8 | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as rs200268422; called by muse, mutect2, varscan2
- ADAMTS10 | c.2701G>C p.D901H | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.871); catalogued as COSV54357474, COSV54358510; called by muse, mutect2, varscan2
- ALB | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs760943157, CM147063; called by muse, mutect2
- ALG10B | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 43/399 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.048); catalogued as COSV58145527; called by muse, mutect2, varscan2
- ANKZF1 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99850956; called by muse, mutect2, varscan2
- AP5B1 | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752882879; called by muse, mutect2, varscan2
- ARFGEF3 | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs776202393; called by muse, mutect2
- ASXL2 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 26/284 reads (9%) | catalogued as COSV55460371; called by muse, mutect2
- ATP13A1 | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs977957559; called by muse, mutect2
- AURKC | c.718G>C p.E240Q (on ENST00000302804 / NM_001015878.2; = p.E206Q on NM_003160.3) | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV57141596; called by muse, mutect2
- B3GALNT1 | c.147G>T p.W49C | Missense Mutation (SNP) | VAF 104/782 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV57579710; called by muse, mutect2, varscan2
- BNC2 | c.2520G>C p.K840N | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66151273; called by muse, mutect2
- CCDC39 | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1346270869, COSV99868867; called by muse, mutect2
- CCDC60 | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV59542820; called by muse, mutect2
- CDH8 | c.844C>G p.H282D | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54888464; called by muse, mutect2, varscan2
- CFAP94 | c.1292C>T p.A431V (on ENST00000320267 / NM_001352064.2; = p.A437V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/196 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV57231863; called by muse, mutect2
- CREG2 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs1013323058; called by muse, mutect2, varscan2
- CTNNA2 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as COSV100785717; called by muse, mutect2, varscan2
- DCBLD2 | c.1993G>C p.A665P | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV54585533; called by muse, mutect2, varscan2
- DCC | c.3279G>C p.Q1093H | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs1396521165; called by muse, mutect2
- DENND2C | c.244G>C p.D82H | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs1166964417; called by muse, mutect2
- DISP2 | c.1435G>T p.E479* | Nonsense Mutation (SNP) | VAF 25/249 reads (10%) | catalogued as rs1158605214, COSV51127236; called by muse, mutect2, varscan2
- DOCK7 | c.4882G>A p.E1628K (on ENST00000635253 / NM_001367561.1; = p.E1597K on NM_033407.3) | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as rs138393645; called by muse, mutect2
- FAM151A | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs375087607; called by muse, mutect2
- FANCM | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as rs200017450, COSV57497773; ClinVar: uncertain significance; called by muse, mutect2
- FBXO34 | c.1310G>C p.R437T | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.079); catalogued as COSV58253400, COSV58254120; called by muse, mutect2
- GABRA1 | c.844A>G p.R282G | Missense Mutation (SNP) | VAF 71/276 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50098437; called by muse, mutect2, varscan2
- GCFC2 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs755796921; called by muse, mutect2
- GFOD2 | c.1070C>T p.S357F | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as COSV52057615; called by muse, mutect2
- GMEB1 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1226593942; called by muse, mutect2
- GPRASP2 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 44/136 reads (32%) | catalogued as COSV59990181; called by muse, mutect2, varscan2
- GSX2 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs759859762; called by muse, mutect2
- H2AC17 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.09); catalogued as COSV58153807; called by muse, mutect2
- HERC4 | c.2932G>T p.E978* (on ENST00000395198 / NM_022079.3; = p.E970* on NM_015601.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/145 reads (15%) | catalogued as COSV99517461; called by muse, mutect2, varscan2
- HP1BP3 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV56562665; called by muse, mutect2, varscan2
- IGSF10 | c.4523C>G p.S1508C | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.338); catalogued as COSV56781835; called by muse, mutect2
- KIDINS220 | c.2819G>A p.R940K | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.37); catalogued as rs777086803; called by muse, mutect2, varscan2
- KIF24 | c.3745G>T p.E1249* | Nonsense Mutation (SNP) | VAF 24/200 reads (12%) | catalogued as rs1380719284; called by muse, mutect2, varscan2
- KLF10 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as rs776282556; called by muse, mutect2
- KMT2D | c.7608C>G p.F2536L | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV56424582, COSV99983763; called by muse, mutect2
- KMT2D | c.3668C>G p.S1223* | Nonsense Mutation (SNP) | VAF 19/203 reads (9%) | catalogued as COSV99985270; called by muse, mutect2
- KMT2D | c.1657C>G p.P553A | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.168); catalogued as COSV56424212, COSV56489850; called by muse, mutect2, varscan2
- LAMB1 | c.2288C>T p.S763F | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs972600075; called by muse, mutect2
- LIFR | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 120/397 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV54689007; called by muse, mutect2, varscan2
- MCPH1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs1390169606; called by muse, mutect2
- MIB2 | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1169959430; called by muse, mutect2
- NAALADL1 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 27/548 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV60523012; called by muse, mutect2
- NLGN4X | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 131/224 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs943976611, COSV99321935; called by muse, mutect2, varscan2
- NPAS4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 22/525 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.187); catalogued as rs1210527164; called by muse, mutect2
- OR10P1 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100548198; called by muse, mutect2, varscan2
- OR8K5 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57888517; called by muse, mutect2
- PAF1 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 28/307 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); catalogued as rs369820864; called by muse, mutect2
- PCDH17 | c.3107C>G p.S1036* | Nonsense Mutation (SNP) | VAF 15/151 reads (10%) | catalogued as COSV64974018; called by muse, mutect2, varscan2
- PCDHA5 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 44/357 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); catalogued as COSV65349670; called by muse, mutect2, varscan2
- PITPNM1 | c.821C>T p.P274L | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs754527358; called by muse, mutect2, varscan2
- PLD5 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.827); catalogued as rs892939595; called by muse, mutect2
- POLG2 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs781955943; called by muse, mutect2, varscan2
- PREX2 | c.2765A>T p.K922I | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV99905132; called by muse, mutect2, varscan2
- PRX | c.2290C>T p.P764S | Missense Mutation (SNP) | VAF 27/340 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs142884199; called by muse, mutect2
- PTPRA | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53780026; called by muse, mutect2
- RELN | c.6538G>A p.D2180N | Missense Mutation (SNP) | VAF 154/346 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.869); catalogued as rs1464080801, COSV58991449; called by muse, varscan2
- RNF187 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030185199, COSV59959857, COSV59960193; called by muse, mutect2, varscan2
- RTCA | c.534G>C p.L178F | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1231902177; called by muse, mutect2, varscan2
- SAMD9 | c.3350C>G p.S1117C | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66072799; called by muse, varscan2
- SCN9A | c.5361G>C p.E1787D (on ENST00000303354; = p.E1776D on NM_002977.3) | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1017717952; called by muse, mutect2
- SERPINA5 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 56/231 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV61573530, COSV61573761; called by muse, mutect2, varscan2
- SLC25A16 | c.525C>G p.F175L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs1321676763, COSV56265984; called by muse, mutect2
- SNAP91 | c.155C>A p.T52N | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV99536999; called by muse, mutect2, varscan2
- ST6GAL2 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | PolyPhen probably damaging (0.978); catalogued as rs372148383; called by muse, mutect2, varscan2
- STXBP2 | c.1597C>T p.R533W | Missense Mutation (SNP) | VAF 51/296 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747482928; called by muse, mutect2, varscan2
- TASOR | c.4745C>T p.T1582I (on ENST00000355628 / NM_001365636.2; = p.T1206I on NM_015224.3) | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs72879331; called by muse, mutect2, varscan2
- TBC1D13 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as COSV56354362; called by muse, mutect2
- TGFBR2 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99847016; called by muse, mutect2, varscan2
- TMEM168 | c.849C>G p.F283L | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs1355776317; called by muse, mutect2
- WDR49 | c.1073G>A p.G358E (on ENST00000308378 / NM_001366158.1; = p.G699E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/472 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as COSV57706984; called by muse, varscan2
- WFDC8 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.07); catalogued as rs750785099; called by muse, mutect2, varscan2
- ZNF479 | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV58639221; called by muse, mutect2
- ZNF540 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1290362936, COSV100329871; called by muse, mutect2
- ZNF665 | c.1826G>A p.R609K (on ENST00000600412; = p.R674K on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs377630128; called by muse, mutect2, varscan2
- ZNF71 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.015); catalogued as rs1386725020; called by muse, varscan2
- AAGAB | c.932C>G p.S311C | Missense Mutation (SNP) | VAF 14/223 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ABCF1 | c.2113G>C p.E705Q (on ENST00000326195 / NM_001025091.2; = p.E667Q on NM_001090.3) | Missense Mutation (SNP) | VAF 20/327 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); called by muse, mutect2
- ABO | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 44/494 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.402); called by muse, mutect2
- AK9 | c.3867G>C p.L1289F | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2
- AMH | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ANO3 | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2
- AR | c.1784T>A p.L595Q | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARMC9 | c.1830G>C p.Q610H | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2
- ARR3 | c.684C>G p.I228M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASIC5 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.01); called by muse, mutect2
- ASPM | c.7409G>A p.R2470K | Missense Mutation (SNP) | VAF 29/554 reads (5%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.855); called by muse, mutect2
- BECN1 | c.333C>A p.N111K | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRWD3 | c.3931G>A p.E1311K | Missense Mutation (SNP) | VAF 30/168 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- C6orf120 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- CASP1 | c.1127C>G p.S376* (on ENST00000436863 / NM_033292.4; = p.S355* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 30/122 reads (25%) | called by muse, mutect2, varscan2
- CEP295NL | c.823C>G p.R275G | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- CHAT | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CHST5 | c.971G>A p.W324* | Nonsense Mutation (SNP) | VAF 102/329 reads (31%) | called by muse, mutect2, varscan2
- CHST6 | c.537C>A p.F179L | Missense Mutation (SNP) | VAF 36/590 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); called by muse, mutect2
- COL25A1 | c.1718A>G p.K573R | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.599); called by muse, mutect2
- CPNE7 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- CRIP1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.309); called by muse, mutect2
- CSHL1 | c.85A>C p.T29P | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CUL3 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 25/188 reads (13%) | called by muse, mutect2, varscan2
- CYFIP1 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- DENND1C | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- DNASE2 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EIF4A1 | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 19/166 reads (11%) | called by muse, varscan2
- EIF4A2 | c.514_517dup p.P174Ffs*12 | Frame Shift Ins (INS) | VAF 14/132 reads (11%) | called by mutect2, pindel
- FAT4 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FNDC3A | c.2240C>T p.S747L (on ENST00000492622 / NM_001079673.2; = p.S691L on NM_014923.5) | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); called by muse, mutect2
- FZD9 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- GANC | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 30/205 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- GPC1 | c.920C>T p.T307I | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- HADHB | c.44C>G p.S15* | Nonsense Mutation (SNP) | VAF 12/398 reads (3%) | called by muse, mutect2
- HSPH1 | c.2068G>C p.D690H | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.182); called by muse, mutect2
- HUWE1 | c.6916C>T p.H2306Y | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- HVCN1 | c.309C>A p.V103= | Splice Region (SNP) | VAF 14/99 reads (14%) | called by muse, mutect2, varscan2
- IL12RB1 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.057); called by muse, mutect2
- IQGAP1 | c.4681C>G p.L1561V | Missense Mutation (SNP) | VAF 16/243 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.03); called by muse, mutect2
- KIF1B | c.1531G>A p.E511K (on ENST00000377086 / NM_001365952.1; = p.E465K on NM_015074.3) | Missense Mutation (SNP) | VAF 34/410 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2
- KIF22 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KMT2D | c.3158C>G p.S1053C | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- KRT6B | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 20/452 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KRT82 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2
- LAMA5 | c.955A>T p.R319W | Missense Mutation (SNP) | VAF 81/241 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LIMS1 | c.128A>C p.Q43P | Missense Mutation (SNP) | VAF 60/666 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2
- LTBP3 | c.3776G>C p.R1259P (on ENST00000301873 / NM_001130144.3; = p.R1212P on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/321 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- LURAP1L | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MED1 | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 11/237 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.187); called by muse, mutect2
- MUC16 | c.32545A>T p.T10849S | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.115); called by muse, mutect2
- MYH13 | c.5752G>A p.E1918K | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- MYO6 | c.3721C>T p.L1241F (on ENST00000369981; = p.L1231F on NM_004999.4) | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- MYT1L | c.2354G>C p.C785S | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- NEK9 | c.2935C>T p.L979F | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NUTM2A | c.2575C>G p.Q859E | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by mutect2, varscan2
- OR10P1 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR2A12 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2
- OR2T8 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 42/302 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- PARP1 | c.1563G>C p.K521N | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2
- PARP1 | c.1314G>C p.K438N | Missense Mutation (SNP) | VAF 19/337 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); called by muse, mutect2
- PCDH12 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PDE3A | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PGD | c.1120G>T p.G374* | Nonsense Mutation (SNP) | VAF 55/167 reads (33%) | called by muse, mutect2, varscan2
- PREX1 | c.2032dup p.L678Pfs*62 | Frame Shift Ins (INS) | VAF 73/267 reads (27%) | called by mutect2, pindel, varscan2
- PTCD3 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PUS7L | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PXMP4 | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 29/370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RAPGEF5 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RBBP6 | c.2618C>G p.S873C | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RGPD8 | c.5298_*6delinsT | Nonstop Mutation (DEL) | VAF 36/217 reads (17%) | called by pindel, varscan2*
- RSL24D1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.368); called by muse, mutect2
- RUNX2 | c.1022-1G>A p.X341_splice | Splice Site (SNP) | VAF 14/252 reads (6%) | called by muse, mutect2
- SAFB2 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2
- SAMD7 | c.403G>T p.A135S | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- SESTD1 | c.724C>T p.L242F | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); called by muse, mutect2
- SF3A3 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- SLC17A8 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.11); called by muse, mutect2
- SLITRK3 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- SMC6 | c.1708G>C p.E570Q | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- SMYD4 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- SOX6 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 32/318 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- SPATA6 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- STYK1 | c.851C>G p.S284C | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); called by muse, mutect2
- SYNE1 | c.18010C>G p.Q6004E (on ENST00000367255 / NM_182961.4; = p.Q5933E on NM_033071.3) | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.18); called by muse, mutect2
- SYNJ1 | c.2923G>C p.D975H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2
- TANC2 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 32/595 reads (5%) | called by muse, mutect2
- TFIP11 | c.1415T>C p.L472P | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- TMEM223 | c.261C>G p.F87L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2
- TP73 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); called by muse, mutect2
- TRIM23 | c.485A>T p.K162M | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSPAN17 | c.156C>G p.I52M | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- UBA7 | c.751G>T p.G251W | Missense Mutation (SNP) | VAF 96/247 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2NL | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- UBE4A | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.154); called by muse, varscan2
- UPF2 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VPS13C | c.5333dup p.A1779Sfs*9 (on ENST00000644861 / NM_020821.3; = p.A1736Sfs*9 on NM_017684.5) | Frame Shift Ins (INS) | VAF 51/258 reads (20%) | called by mutect2, pindel, varscan2
- VPS50 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 21/312 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.383); called by muse, mutect2
- WDR17 | c.1858G>C p.E620Q | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- WEE2 | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- ZFYVE9 | c.3241G>C p.E1081Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF318 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 35/441 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2
- ZNF630 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF738 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ZNF85 | c.210C>G p.I70M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ZSWIM9 | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.045); called by muse, mutect2
- ABCA1 | c.5991C>T p.I1997= | Silent (SNP) | VAF 35/500 reads (7%) | called by muse, mutect2
- AMH | c.804C>T p.T268= | Silent (SNP) | VAF 56/165 reads (34%) | catalogued as rs1159978819; called by muse, mutect2, varscan2
- APEX1 | c.883T>C p.L295= | Silent (SNP) | VAF 64/358 reads (18%) | catalogued as rs1353080676; called by muse, mutect2, varscan2
- C1QTNF4 | c.861C>T p.L287= | Silent (SNP) | VAF 22/287 reads (8%) | catalogued as rs200189635, COSV100209237; called by muse, mutect2
- C1QTNF4 | c.387C>T p.G129= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as rs778713060; called by muse, mutect2, varscan2
- C4orf51 | c.432G>C p.V144= | Silent (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2
- CCHCR1 | c.1350G>A p.V450= | Silent (SNP) | VAF 133/312 reads (43%) | called by muse, mutect2, varscan2
- CD68 | c.63G>A p.G21= | Silent (SNP) | VAF 9/122 reads (7%) | called by muse, mutect2
- CELF5 | c.477C>T p.V159= | Silent (SNP) | VAF 9/170 reads (5%) | catalogued as rs1193927332; called by muse, mutect2
- CERS3 | c.435C>T p.I145= | Silent (SNP) | VAF 13/226 reads (6%) | catalogued as COSV99431712; called by muse, mutect2
- CNMD | c.435C>T p.G145= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs746623684, COSV65032769; called by muse, mutect2
- COPG2 | c.384C>G p.L128= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1554452983; called by muse, mutect2
- DMAC1 | c.174G>A p.L58= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- DZIP1L | c.597G>A p.K199= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as rs926567981, COSV59522212; called by muse, mutect2, varscan2
- EIF4A1 | c.216G>C p.V72= | Silent (SNP) | VAF 16/178 reads (9%) | called by muse, mutect2
- ESCO2 | c.1614C>T p.I538= | Silent (SNP) | VAF 66/365 reads (18%) | called by muse, mutect2, varscan2
- FSHR | c.1965G>A p.R655= | Silent (SNP) | VAF 40/460 reads (9%) | called by muse, mutect2
- GNPAT | c.144G>A p.L48= | Silent (SNP) | VAF 12/230 reads (5%) | called by muse, mutect2
- GON4L | c.3681G>A p.V1227= | Silent (SNP) | VAF 56/562 reads (10%) | catalogued as rs759665238, COSV99675951; called by muse, mutect2, varscan2
- HOXB5 | c.594G>A p.R198= | Silent (SNP) | VAF 17/218 reads (8%) | called by muse, mutect2
- HOXC12 | c.369G>A p.A123= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- IGLV3-19 | c.255A>T p.S85= | Silent (SNP) | VAF 66/247 reads (27%) | catalogued as rs575297053; called by muse, mutect2, varscan2
- IMMT | c.1302G>A p.L434= | Silent (SNP) | VAF 48/506 reads (9%) | called by muse, mutect2
- IWS1 | c.1227G>A p.K409= | Silent (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- JAM2 | c.300A>C p.T100= | Silent (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- KANSL1L | c.2595C>T p.D865= | Silent (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- KBTBD12 | c.1614C>T p.L538= | Silent (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- KCNC1 | c.657G>C p.V219= | Silent (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- KCNC3 | c.273G>A p.V91= | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2
- KCNE1 | c.375G>A p.T125= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs767686634, COSV61607657; called by mutect2, varscan2
- KYNU | c.657G>A p.L219= | Silent (SNP) | VAF 75/272 reads (28%) | catalogued as COSV51582117; called by muse, mutect2, varscan2
- LAMA1 | c.7596G>A p.E2532= | Silent (SNP) | VAF 29/215 reads (13%) | catalogued as rs779174649; called by muse, mutect2, varscan2
- LRRC15 | c.1608G>A p.Q536= | Silent (SNP) | VAF 14/383 reads (4%) | catalogued as rs1276267487; called by muse, mutect2
- MPP2 | c.1596C>T p.I532= (on ENST00000461854 / NM_001278372.2; = p.I508= on NM_005374.5) | Silent (SNP) | VAF 22/163 reads (13%) | called by muse, mutect2, varscan2
- NECTIN2 | c.918C>T p.S306= | Silent (SNP) | VAF 16/193 reads (8%) | catalogued as rs139448288; called by muse, mutect2
- NEXMIF | c.1752G>A p.L584= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as COSV99282077; called by muse, mutect2, varscan2
- NINL | c.1086C>T p.A362= | Silent (SNP) | VAF 60/227 reads (26%) | called by muse, mutect2, varscan2
- NLRP3 | c.666C>T p.F222= | Silent (SNP) | VAF 51/387 reads (13%) | called by muse, mutect2, varscan2
- NOL3 | c.318C>T p.D106= | Silent (SNP) | VAF 22/51 reads (43%) | called by muse, mutect2, varscan2
- NOP2 | c.2103A>G p.R701= (on ENST00000322166 / NM_001258308.2; = p.R697= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 87/502 reads (17%) | called by muse, mutect2, varscan2
- NRXN3 | c.2256C>T p.I752= (on ENST00000335750 / NM_001330195.2; = p.I379= on NM_004796.6) | Silent (SNP) | VAF 8/190 reads (4%) | called by muse, mutect2
- NT5DC3 | c.54G>A p.A18= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- NTRK3 | c.1338G>A p.L446= | Silent (SNP) | VAF 20/222 reads (9%) | catalogued as rs1247832786, COSV100447761; called by muse, mutect2
- ODF3L1 | c.519C>T p.V173= | Silent (SNP) | VAF 57/282 reads (20%) | catalogued as COSV59820198; called by muse, mutect2, varscan2
- PAN3 | c.2370C>T p.I790= | Silent (SNP) | VAF 64/242 reads (26%) | called by muse, mutect2, varscan2
- PCDH17 | c.1986G>T p.V662= | Silent (SNP) | VAF 86/327 reads (26%) | called by muse, mutect2, varscan2
- PCDHGC5 | c.1968C>G p.L656= | Silent (SNP) | VAF 34/220 reads (15%) | called by muse, mutect2, varscan2
- PLAGL1 | c.573G>A p.Q191= | Silent (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- PLD4 | c.999G>A p.E333= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV66915377; called by muse, mutect2, varscan2
- PLEKHM3 | c.741C>T p.S247= | Silent (SNP) | VAF 60/274 reads (22%) | catalogued as rs1433433570; called by muse, mutect2, varscan2
- PPM1E | c.1368G>A p.E456= | Silent (SNP) | VAF 18/248 reads (7%) | catalogued as rs1240402723, COSV57573601; called by muse, mutect2
- PRR23C | c.726C>T p.H242= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as rs755928326, COSV101356482, COSV101356484; called by muse, mutect2, varscan2
- PRX | c.1878C>T p.V626= | Silent (SNP) | VAF 52/748 reads (7%) | called by muse, mutect2
- RAB3IL1 | c.912G>A p.L304= | Silent (SNP) | VAF 22/277 reads (8%) | catalogued as rs1565358318; called by muse, mutect2
- REG3G | c.285T>C p.I95= | Silent (SNP) | VAF 60/189 reads (32%) | called by muse, mutect2, varscan2
- RUSF1 | c.1406G>A p.*469= | Silent (SNP) | VAF 12/114 reads (11%) | called by muse, mutect2
- RYR2 | c.4554C>G p.L1518= | Silent (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- S1PR4 | c.783G>A p.L261= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2
- SBSN | c.1191G>C p.V397= | Silent (SNP) | VAF 82/287 reads (29%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.1998C>T p.F666= | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2
- SKOR2 | c.1650C>T p.G550= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs1410154443; called by mutect2, varscan2
- SLC5A12 | c.1158C>G p.L386= | Silent (SNP) | VAF 46/182 reads (25%) | called by muse, mutect2, varscan2
- SMG8 | c.1755A>G p.K585= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- SPIDR | c.2541G>A p.V847= | Silent (SNP) | VAF 31/305 reads (10%) | called by muse, mutect2
- TAS1R1 | c.2391G>A p.L797= | Silent (SNP) | VAF 51/381 reads (13%) | catalogued as COSV100039687; called by muse, mutect2, varscan2
- TAS2R39 | c.99C>T p.L33= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV101489391; called by muse, mutect2
- TENM2 | c.810C>A p.L270= (on ENST00000518659 / NM_001122679.2; = p.L79= on NM_001080428.3) | Silent (SNP) | VAF 20/282 reads (7%) | called by muse, mutect2
- TIPARP | c.234G>A p.Q78= | Silent (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- TTC30A | c.1869C>T p.G623= | Silent (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2
- TTN | c.71184C>G p.L23728= (on ENST00000591111; = p.L16304= on NM_003319.4) | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as COSV59951451; called by muse, mutect2
- UNC13A | c.3000G>A p.V1000= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- WDPCP | c.1464G>A p.L488= | Silent (SNP) | VAF 16/282 reads (6%) | catalogued as COSV99705642; called by muse, mutect2
- WDR26 | c.1023G>A p.T341= (on ENST00000414423 / NM_001379403.1; = p.T241= on NM_025160.7) | Silent (SNP) | VAF 25/432 reads (6%) | catalogued as rs776263058, COSV54358035; called by muse, mutect2
- ZNF569 | c.1845C>T p.F615= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV57595408; called by muse, mutect2, varscan2
- ZNF804A | c.751A>C p.R251= | Silent (SNP) | VAF 37/149 reads (25%) | catalogued as COSV100166598; called by muse, mutect2, varscan2
- AC107023.1 | n.25+7687G>A | Intron (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- AC107023.1 | chr12:40444275 G>A | 5'Flank (SNP) | VAF 45/227 reads (20%) | called by muse, mutect2, varscan2
- AC136604.1 | chr5:179652295 G>A | 3'Flank (SNP) | VAF 33/540 reads (6%) | called by muse, mutect2
- ASIC4 | c.-75G>T | 5'UTR (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- BRF2 | c.215-146C>T | Intron (SNP) | VAF 7/127 reads (6%) | called by muse, mutect2
- CACNA1G | c.4422+103G>A | Intron (SNP) | VAF 57/279 reads (20%) | catalogued as rs1018471376, COSV61731733; called by muse, mutect2, varscan2
- CDH8 | c.*734C>T | 3'UTR (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- CYTH1 | c.1119-847C>T | Intron (SNP) | VAF 63/221 reads (29%) | called by muse, mutect2, varscan2
- DCHS2 | n.1052C>T | RNA (SNP) | VAF 39/339 reads (12%) | catalogued as rs199574901, COSV59725564, COSV59740743; called by muse, mutect2, varscan2
- EIF4A1 | c.515-127G>A | Intron (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1915C>G | 3'UTR (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- FRMD4A | c.-21C>T | 5'UTR (SNP) | VAF 16/172 reads (9%) | catalogued as rs1357380595; called by muse, mutect2
- GYS1 | c.*444C>T | 3'UTR (SNP) | VAF 27/238 reads (11%) | catalogued as rs557171534; called by muse, varscan2
- KALRN | c.-14G>C | 5'UTR (SNP) | VAF 15/183 reads (8%) | called by muse, mutect2
- LINC01588 | n.834G>A | RNA (SNP) | VAF 18/192 reads (9%) | catalogued as rs773698832; called by muse, mutect2
- LRRIQ3 | c.573+1784G>C | Intron (SNP) | VAF 18/185 reads (10%) | called by muse, mutect2, varscan2
- NBPF22P | n.940G>A | RNA (SNP) | VAF 75/280 reads (27%) | catalogued as rs1045123674; called by muse, mutect2, varscan2
- PCDHGC4 | c.2442+31G>C | Intron (SNP) | VAF 38/223 reads (17%) | called by muse, mutect2, varscan2
- PDE10A | c.106+91608C>A | Intron (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2, varscan2
- PEX26 | c.230+118C>T | Intron (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- POM121L9P | n.1303G>A | RNA (SNP) | VAF 50/673 reads (7%) | catalogued as rs557153775; called by muse, mutect2
- PSMF1 | c.*1173G>A | 3'UTR (SNP) | VAF 21/270 reads (8%) | called by muse, mutect2
- RAB17 | c.*455G>A | 3'UTR (SNP) | VAF 14/144 reads (10%) | catalogued as rs1047724, COSV52815809; called by muse, mutect2, varscan2
- RBBP4 | c.*53G>C | 3'UTR (SNP) | VAF 11/138 reads (8%) | catalogued as COSV100995208; called by muse, mutect2
- RELL2 | c.-1C>G | 5'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- RNF207 | c.324+243G>T | Intron (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
- RPSAP52 | n.427G>A | RNA (SNP) | VAF 31/363 reads (9%) | catalogued as rs1313627726; called by muse, mutect2
- TIMP1 | c.453+150C>T | Intron (SNP) | VAF 7/101 reads (7%) | called by muse, mutect2
- TNFRSF25 | c.598+46G>A | Intron (SNP) | VAF 41/433 reads (9%) | catalogued as rs1193015636; called by muse, mutect2
- TUBB7P | n.563C>G | RNA (SNP) | VAF 29/286 reads (10%) | called by muse, mutect2, varscan2
- UNC45A | chr15:90935274 C>T | 5'Flank (SNP) | VAF 24/216 reads (11%) | called by muse, mutect2
- USP46 | c.999+19C>G | Intron (SNP) | VAF 14/197 reads (7%) | called by muse, mutect2
- VSIG10L | c.*45G>C | 3'UTR (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2, varscan2
- ZC3H14 | c.2006-34G>C | Intron (SNP) | VAF 29/374 reads (8%) | called by muse, mutect2
- ZNF300 | c.-9G>C | 5'UTR (SNP) | VAF 33/167 reads (20%) | catalogued as COSV51053898; called by muse, mutect2, varscan2
